Somatic mutation profile of tumor specimen TCGA-4V-A9QU-01A (aliquot TCGA-4V-A9QU-01A-11D-A423-09) from TCGA case TCGA-4V-A9QU, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type AB, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 76.4 years (27,896 days).
Specimen TCGA-4V-A9QU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a11d060-9aad-4a6e-8d0b-2f9a927732e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4V-A9QU-10A (Blood Derived Normal), aliquot TCGA-4V-A9QU-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/290ac2f0-0188-4229-8d39-40176dfd3ba1

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 41/632 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2
- NBEAL2 | c.1059del p.E354Rfs*11 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | catalogued as rs1559590473; called by pindel, varscan2
- NUAK1 | c.1559G>A p.R520Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.287); catalogued as rs117517173; called by muse, mutect2, varscan2
- PDE4D | c.1486A>G p.I496V (on ENST00000340635 / NM_001104631.2; = p.I360V on NM_006203.4) | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.02); catalogued as rs1001030257; called by muse, mutect2
- RECQL | c.224G>T p.W75L | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59086114; called by muse, mutect2
- IMMT | c.211T>A p.F71I | Missense Mutation (SNP) | VAF 12/179 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- INA | c.1180G>T p.A394S | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CLOCK | c.1119C>T p.H373= | Silent (SNP) | VAF 9/183 reads (5%) | called by muse, mutect2
- HLX | c.654C>G p.P218= | Silent (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2, varscan2
- PPEF1 | c.1653A>G p.K551= | Silent (SNP) | VAF 7/180 reads (4%) | called by muse, mutect2
